Somatic mutation profile of tumor specimen C3L-00581-01 (aliquot CPT0007320009) from CPTAC case C3L-00581, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.6 years (19,213 days).
Specimen C3L-00581-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3f9ef1b-e408-48e3-af5b-de192afc1cd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00581-31 (Blood Derived Normal), aliquot CPT0002780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42e36755-a116-40a8-8be7-18bf4262a8d9

The open-access MAF lists 105 somatic variants for this specimen: 73 protein-altering or splice-affecting, 18 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 18, Frame Shift Del 10, Intron 9, Frame Shift Ins 4, Splice Site 3, 5'UTR 2, Nonsense Mutation 2, RNA 1, In Frame Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1416del p.S473Vfs*98 | Frame Shift Del (DEL) | VAF 43/141 reads (30%) | catalogued as rs1060503731; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADD2 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV52459516; called by muse, varscan2
- BICC1 | c.2445C>A p.N815K | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99570989; called by muse, mutect2, varscan2
- CLPTM1L | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.295); catalogued as rs762247898; called by muse, mutect2, varscan2
- DNAH2 | c.4045G>T p.E1349* | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | catalogued as COSV66727272; called by muse, mutect2, varscan2
- ERCC3 | c.2263G>C p.D755H | Missense Mutation (SNP) | VAF 88/414 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.134); catalogued as COSV53425589; called by muse, mutect2, varscan2
- FLG2 | c.6790C>T p.H2264Y | Missense Mutation (SNP) | VAF 73/439 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as rs770971156; called by muse, mutect2, varscan2
- MYO3A | c.3576G>A p.M1192I | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56349084; called by muse, mutect2, varscan2
- PYGL | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 15/382 reads (4%) | catalogued as rs1327581647; called by muse, mutect2
- RTN1 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs1014346787, COSV50718522; called by muse, mutect2, varscan2
- SCGB3A2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs774802794; called by muse, mutect2, varscan2
- SFSWAP | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as rs1170451411; called by muse, mutect2, varscan2
- SHROOM1 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60581100; called by muse, mutect2
- SLC39A14 | c.434_436del p.E145del | In Frame Del (DEL) | VAF 15/111 reads (14%) | catalogued as rs772125874; called by pindel, varscan2
- STEAP4 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1326771233; called by muse, mutect2, varscan2
- THEMIS | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs765387427, COSV100965532, COSV64070629; called by muse, mutect2, varscan2
- ZNF267 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV56256255; called by muse, mutect2, varscan2
- ZNF536 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 75/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62821960; called by muse, mutect2, varscan2
- ZNF852 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101465013; called by muse, mutect2
- ANKRD26 | c.2171G>T p.S724I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- AQR | c.3894A>C p.R1298S | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATXN2L | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- BCORL1 | c.3049del p.H1017Tfs*33 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- BPIFB6 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CC2D1A | c.2074-2A>G p.X692_splice | Splice Site (SNP) | VAF 51/238 reads (21%) | called by muse, mutect2, varscan2
- CDH2 | c.439T>A p.F147I | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK10 | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- COL7A1 | c.2142_2148del p.Y715Ffs*37 | Frame Shift Del (DEL) | VAF 62/346 reads (18%) | called by mutect2, pindel, varscan2
- CPNE5 | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CSAG3 | c.65del p.K22Rfs*9 | Frame Shift Del (DEL) | VAF 32/193 reads (17%) | called by mutect2, pindel, varscan2
- CTBP1 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- DKK4 | c.500A>T p.K167M | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.9739G>C p.D3247H | Missense Mutation (SNP) | VAF 71/357 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- GSDMC | c.301A>C p.I101L | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPACAM2 | c.307C>A p.P103T (on ENST00000394468 / NM_001039372.4; = p.P91T on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICAM5 | c.1847A>G p.E616G | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCNA10 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KLHL22 | c.261del p.E87Dfs*6 | Frame Shift Del (DEL) | VAF 28/156 reads (18%) | called by mutect2, pindel, varscan2
- KPNB1 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- LPIN1 | c.482dup p.S162Vfs*10 | Frame Shift Ins (INS) | VAF 68/338 reads (20%) | called by mutect2, pindel, varscan2
- LY75 | c.1344T>G p.D448E | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- MCTP1 | c.2449del p.V817Lfs*9 | Frame Shift Del (DEL) | VAF 21/159 reads (13%) | called by mutect2, pindel, varscan2
- NUP188 | c.2254C>A p.L752M | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- OR6C74 | c.332_333del p.F111Sfs*8 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- PCMTD2 | c.713T>A p.V238E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, varscan2
- PLEKHA6 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PRG4 | c.3497_3498insT p.G1167Rfs*21 | Frame Shift Ins (INS) | VAF 72/420 reads (17%) | called by mutect2, pindel*, varscan2
- PRRC2C | c.8200-1G>A p.X2734_splice (on ENST00000367742; = p.X2732_splice on NM_015172.4) | Splice Site (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- RCBTB2 | c.103del p.S35Pfs*10 | Frame Shift Del (DEL) | VAF 27/198 reads (14%) | called by mutect2, pindel, varscan2
- RYR2 | c.2679G>C p.W893C | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA7A | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SH3GL1 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 105/566 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SMC1B | c.759A>C p.R253S | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SORL1 | c.4407del p.R1470Dfs*43 | Frame Shift Del (DEL) | VAF 95/502 reads (19%) | called by mutect2, pindel, varscan2
- SPP1 | c.404A>G p.D135G (on ENST00000395080 / NM_001040058.2; = p.D121G on NM_000582.2) | Missense Mutation (SNP) | VAF 68/460 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STOML2 | c.218T>A p.I73N | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SYTL2 | c.584-2A>G p.X195_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | called by muse, varscan2
- TNKS2 | c.910dup p.T304Nfs*8 | Frame Shift Ins (INS) | VAF 21/124 reads (17%) | called by mutect2, pindel, varscan2
- TONSL | c.4055T>C p.L1352P | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- UFSP2 | c.727_728del p.F243Qfs*4 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- UHRF2 | c.1811T>G p.L604W | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VHL | c.413dup p.S139Ifs*5 | Frame Shift Ins (INS) | VAF 84/413 reads (20%) | called by mutect2, pindel, varscan2
- WNK1 | c.6272A>C p.Q2091P (on ENST00000315939 / NM_018979.4; = p.Q1843P on NM_014823.3) | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- XRN2 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZBTB48 | c.1459C>A p.H487N | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H12C | c.285T>A p.N95K | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFP3 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF26 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF33A | c.1774A>G p.K592E (on ENST00000458705 / NM_006974.3; = p.K593E on NM_006954.2) | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ZNF568 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- ZNF583 | c.1362T>G p.H454Q | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF692 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- ZSCAN2 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARMC7 | c.462C>T p.A154= | Silent (SNP) | VAF 58/311 reads (19%) | called by muse, mutect2, varscan2
- BCR | c.1164C>T p.C388= | Silent (SNP) | VAF 37/249 reads (15%) | called by muse, mutect2, varscan2
- HOXB4 | c.57A>C p.P19= | Silent (SNP) | VAF 78/469 reads (17%) | catalogued as rs1205895976, COSV60177977; called by muse, mutect2, varscan2
- KCNQ1 | c.1866C>A p.G622= | Silent (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- KIF20A | c.546G>A p.R182= | Silent (SNP) | VAF 32/249 reads (13%) | catalogued as rs1483175198; called by muse, mutect2, varscan2
- LRRC8D | c.1662C>T p.A554= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs574691834; called by muse, mutect2, varscan2
- MLXIP | c.2530C>T p.L844= | Silent (SNP) | VAF 33/160 reads (21%) | called by muse, mutect2, varscan2
- OR56A3 | c.282G>A p.R94= | Silent (SNP) | VAF 37/362 reads (10%) | called by muse, mutect2, varscan2
- PDIA5 | c.807T>C p.T269= | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- PKP3 | c.687G>T p.L229= | Silent (SNP) | VAF 44/241 reads (18%) | called by muse, mutect2, varscan2
- RSC1A1 | c.909T>C p.D303= | Silent (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- SEC14L1 | c.2059C>T p.L687= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as rs377362452; called by muse, mutect2, varscan2
- SLC13A2 | c.153T>C p.T51= | Silent (SNP) | VAF 34/191 reads (18%) | called by muse, mutect2, varscan2
- STEAP4 | c.177C>A p.P59= | Silent (SNP) | VAF 53/250 reads (21%) | called by muse, mutect2, varscan2
- STOML2 | c.219C>A p.I73= | Silent (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.2478G>A p.A826= | Silent (SNP) | VAF 66/357 reads (18%) | catalogued as rs372465003; called by muse, mutect2, varscan2
- UHRF2 | c.1810T>C p.L604= | Silent (SNP) | VAF 45/203 reads (22%) | called by muse, mutect2, varscan2
- VPS13D | c.4170G>A p.R1390= | Silent (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.1528A>C | RNA (SNP) | VAF 25/158 reads (16%) | called by muse, mutect2, varscan2
- CHCHD3 | c.170-10087G>C | Intron (SNP) | VAF 81/507 reads (16%) | called by muse, mutect2, varscan2
- COPS7A | c.163-252_163-238del | Intron (DEL) | VAF 19/183 reads (10%) | called by mutect2, pindel
- EIF4G3 | c.299+11C>T | Intron (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- FOXM1 | c.1021-9C>G | Intron (SNP) | VAF 50/229 reads (22%) | called by muse, mutect2, varscan2
- GFI1 | c.-5C>T | 5'UTR (SNP) | VAF 83/470 reads (18%) | called by muse, mutect2, varscan2
- HADH | c.133-4891G>C | Intron (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2
- HMGN1 | chr21:39349475 C>G | 5'Flank (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.-11A>G | 5'UTR (SNP) | VAF 17/92 reads (18%) | catalogued as rs1208399434; called by muse, mutect2, varscan2
- RGS11 | c.658-16A>T | Intron (SNP) | VAF 27/181 reads (15%) | called by muse, mutect2, varscan2
- SH3TC1 | c.481+609C>G | Intron (SNP) | VAF 37/238 reads (16%) | called by muse, mutect2, varscan2
- SYP | c.*4+24G>A | Intron (SNP) | VAF 11/170 reads (6%) | catalogued as rs782014669, CR121461; called by muse, mutect2
- WDR11 | c.*32G>A | 3'UTR (SNP) | VAF 61/309 reads (20%) | called by muse, mutect2, varscan2
- ZNF880 | c.269-4338T>C | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as rs1338089749; called by muse, mutect2, varscan2
